Somatic mutation profile of tumor specimen ALCH-B34G-TTR1-A (aliquot ALCH-B34G-TTR1-A-1-0-D-A85H-36) from ALCHEMIST case ALCH-B34G, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 71.8 years (26,224 days).
Specimen ALCH-B34G-TTR1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a8fc53db-c71d-4d1e-9d81-eb8a046de22d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B34G-NB1-A (Blood Derived Normal), aliquot ALCH-B34G-NB1-A-1-0-D-A799-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e4874833-63ad-40f3-984b-b4a7616cd144

The open-access MAF lists 29 somatic variants for this specimen: 17 protein-altering or splice-affecting, 6 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 6, Intron 5, Frame Shift Del 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGEF6 | c.1881del p.K628Nfs*18 | Frame Shift Del (DEL) | VAF 18/116 reads (16%) | catalogued as COSV104377127; called by mutect2, pindel, varscan2
- AUTS2 | c.3337G>A p.D1113N | Missense Mutation (SNP) | VAF 49/406 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.104); catalogued as rs1340203182; called by muse, mutect2, varscan2
- LRRC66 | c.1795A>G p.R599G | Missense Mutation (SNP) | VAF 23/210 reads (11%) | SIFT tolerated (0.47); PolyPhen benign (0.014); catalogued as COSV100603127; called by muse, mutect2, varscan2
- PCDHB10 | c.2033C>T p.P678L | Missense Mutation (SNP) | VAF 83/327 reads (25%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.003); catalogued as rs1160159555; called by muse, mutect2, varscan2
- PDLIM4 | c.916G>A p.A306T | Missense Mutation (SNP) | VAF 120/782 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1223503833; called by muse, mutect2, varscan2
- RNF20 | c.41G>A p.G14D | Missense Mutation (SNP) | VAF 26/321 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.199); catalogued as rs776863021, COSV66355877; called by muse, mutect2
- ANKDD1B | c.1170G>C p.E390D | Missense Mutation (SNP) | VAF 28/316 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.166); called by muse, mutect2
- CLCA4 | c.426del p.K142Nfs*96 | Frame Shift Del (DEL) | VAF 17/148 reads (11%) | called by mutect2, pindel, varscan2
- EIF3E | c.338T>A p.L113H | Missense Mutation (SNP) | VAF 11/219 reads (5%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.841); called by muse, mutect2
- FASLG | c.142C>A p.P48T | Missense Mutation (SNP) | VAF 106/904 reads (12%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- IGLV10-54 | c.271G>A p.A91T | Missense Mutation (SNP) | VAF 31/214 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- OR5D13 | c.475C>A p.L159M | Missense Mutation (SNP) | VAF 10/216 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.616); called by muse, mutect2
- PEX11B | c.665T>C p.L222P | Missense Mutation (SNP) | VAF 17/258 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.072); called by muse, mutect2
- SPC24 | c.413A>G p.Y138C | Missense Mutation (SNP) | VAF 44/411 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TMEM132E | c.649G>A p.E217K (on ENST00000321639; = p.E307K on NM_001304438.2) | Missense Mutation (SNP) | VAF 40/599 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.699); called by muse, mutect2
- WBP1 | c.289G>C p.A97P | Missense Mutation (SNP) | VAF 22/356 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- YAE1 | c.188A>G p.N63S | Missense Mutation (SNP) | VAF 16/208 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); called by muse, mutect2
- CT55 | c.168G>A p.S56= | Silent (SNP) | VAF 22/161 reads (14%) | catalogued as COSV52278464; called by muse, varscan2
- DBX2 | c.36G>A p.A12= | Silent (SNP) | VAF 74/489 reads (15%) | called by muse, mutect2, varscan2
- MXI1 | c.39C>T p.C13= | Silent (SNP) | VAF 10/48 reads (21%) | called by muse, mutect2, varscan2
- PCDHB2 | c.294C>T p.C98= | Silent (SNP) | VAF 20/207 reads (10%) | called by muse, mutect2, varscan2
- RANBP17 | c.1257T>C p.S419= | Silent (SNP) | VAF 8/73 reads (11%) | called by mutect2, varscan2
- SEPTIN9 | c.381G>T p.P127= (on ENST00000427177 / NM_001113491.2; = p.P109= on NM_006640.4) | Silent (SNP) | VAF 65/752 reads (9%) | called by muse, mutect2
- AP1G2 | c.922-15T>G | Intron (SNP) | VAF 35/320 reads (11%) | called by muse, varscan2
- ASXL1 | c.566-43C>T | Intron (SNP) | VAF 18/102 reads (18%) | catalogued as rs575237779; called by muse, mutect2, varscan2
- GPATCH8 | c.*787T>G | 3'UTR (SNP) | VAF 21/278 reads (8%) | called by muse, mutect2
- MFSD13A | c.828+692A>C | Intron (SNP) | VAF 12/148 reads (8%) | called by muse, mutect2
- TUBB8P7 | n.700+217C>A | Intron (SNP) | VAF 51/601 reads (8%) | called by muse, mutect2
- ZNF385D | c.277-714G>A | Intron (SNP) | VAF 23/294 reads (8%) | called by muse, mutect2
